Somatic mutation profile of tumor specimen TCGA-F5-6813-01A (aliquot TCGA-F5-6813-01A-11D-1826-10) from TCGA case TCGA-F5-6813, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.2 years (25,651 days).
Specimen TCGA-F5-6813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab6ddc82-1c1e-4aef-9c81-66311985045b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6813-10A (Blood Derived Normal), aliquot TCGA-F5-6813-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d825a64d-58e9-4f06-b296-3cbd3ffa61cb

The open-access MAF lists 138 somatic variants for this specimen: 103 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 33, Nonsense Mutation 8, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, Splice Site 1, 5'UTR 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 66/92 reads (72%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3610C>T p.R1204W | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199474732, CM000027, CM973234, COSV62201783; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AAGAB | c.911_912del p.D304Gfs*3 | Frame Shift Del (DEL) | VAF 35/67 reads (52%) | catalogued as COSV56018621; called by mutect2, pindel, varscan2
- ACAA2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs745865904, COSV53270717; called by mutect2, varscan2
- ACE | c.3632A>C p.E1211A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99327946; called by muse, mutect2
- ADAM18 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV55855945; called by muse, mutect2
- ADAMTS20 | c.4516G>T p.G1506C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67140280; called by muse, mutect2, varscan2
- AGTPBP1 | c.1606C>T p.R536* (on ENST00000357081 / NM_001330701.2; = p.R496* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 41/170 reads (24%) | catalogued as rs747285262, COSV61271271; called by muse, mutect2, varscan2
- AHCTF1 | c.3929G>A p.R1310K (on ENST00000366508; = p.R1284K on NM_015446.5) | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58256343; called by muse, mutect2
- ASAP2 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55639393; called by muse, mutect2, varscan2
- ASB12 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62857875; called by muse, mutect2, varscan2
- ASNSD1 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.138); catalogued as COSV53623305, COSV53625029; called by muse, mutect2, varscan2
- ATM | c.9008A>G p.N3003S | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs144636562, CM0910531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV99959215; called by muse, mutect2, varscan2
- BRINP2 | c.374T>A p.L125H | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100838548; called by muse, mutect2
- BRIP1 | c.3266C>G p.S1089C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs761278503, COSV52009731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs138900723; called by muse, mutect2, varscan2
- CACNA1S | c.4414C>T p.R1472C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201257304; called by mutect2, varscan2
- CCBE1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761881641, COSV67950286, COSV67951393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCKAR | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs764715715, COSV55164233; called by muse, mutect2, varscan2
- CDON | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55003227; called by muse, mutect2, varscan2
- CFAP43 | c.2132T>A p.L711Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53381730; called by muse, mutect2, varscan2
- CLEC2B | c.183C>A p.Y61* | Nonsense Mutation (SNP) | VAF 78/240 reads (33%) | catalogued as COSV57310753; called by muse, mutect2, varscan2
- COL4A6 | c.4654C>A p.P1552T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57865586; called by muse, mutect2, varscan2
- CTR9 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1346829925, COSV100797411, COSV63729765; called by muse, mutect2, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 40/82 reads (49%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DENND2A | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1275845812, COSV52047275; called by muse, mutect2, varscan2
- DPF3 | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63503440, COSV63503641; called by muse, mutect2
- EBNA1BP2 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52541780; called by muse, mutect2, varscan2
- EFCAB14 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1312338594, COSV64240741; called by muse, mutect2, varscan2
- FAM217B | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV62564105, COSV62565167; called by muse, mutect2, varscan2
- FLCN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD064549, CM1110108, COSV53258110; called by muse, mutect2, varscan2
- FPR1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs547228145, COSV59053059; called by muse, mutect2, varscan2
- FRAS1 | c.8221C>T p.R2741C | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs184784250; called by muse, mutect2, varscan2
- FRMD6 | c.1118C>T p.A373V (on ENST00000344768 / NM_001267046.2; = p.A365V on NM_152330.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs371612348; called by muse, mutect2, varscan2
- GIMAP7 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.172); catalogued as COSV100543619; called by muse, mutect2, varscan2
- H2AW | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64209477, COSV64209728; called by muse, mutect2
- HEXB | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1017856800, COSV99784534; called by muse, mutect2
- HLA-DPA1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV70090465; called by muse, mutect2, varscan2
- HSPA1L | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65149528; called by muse, mutect2, varscan2
- IDH1 | c.1000T>A p.F334I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61643013; called by muse, mutect2, varscan2
- IGSF1 | c.3677G>T p.C1226F | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63840691; called by muse, mutect2, varscan2
- KRT81 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV59811520; called by muse, mutect2, varscan2
- LRCH3 | c.643C>T p.L215= | Splice Region (SNP) | VAF 43/286 reads (15%) | catalogued as COSV58397064; called by muse, mutect2, varscan2
- LRRC4C | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs747329999, COSV53438355; called by muse, mutect2, varscan2
- LRRTM3 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63665376; called by muse, mutect2, varscan2
- LSR | c.1639C>T p.R547W (on ENST00000361790; = p.R528W on NM_015925.6) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1412645432, COSV55888407; called by muse, mutect2, varscan2
- MAGEB2 | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66781956; called by muse, mutect2
- MBIP | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV59255348; called by muse, mutect2, varscan2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MINPP1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV100916804; called by muse, mutect2
- MMP2 | c.713T>A p.L238* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV54605660; called by muse, mutect2, varscan2
- MOS | c.521G>C p.S174T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100323072; called by muse, mutect2, varscan2
- MUC16 | c.10133C>A p.S3378Y | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV101202254; called by muse, mutect2, varscan2
- MUC5B | c.5741C>T p.A1914V | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV71595822; called by muse, mutect2, varscan2
- MYO3A | c.1618A>C p.K540Q | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56351035; called by muse, mutect2, varscan2
- MYO6 | c.1258C>G p.R420G | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64121630; called by muse, mutect2, varscan2
- NCF2 | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV62316826; called by muse, mutect2, varscan2
- NCOR2 | c.5732C>T p.P1911L | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV62305121; called by muse, mutect2, varscan2
- NKX6-1 | c.608T>G p.I203S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.72); catalogued as COSV55686041; called by muse, mutect2, varscan2
- OR6X1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60010536; called by muse, mutect2, varscan2
- PCDH19 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.616); catalogued as COSV55272181; called by muse, varscan2
- PCDHA5 | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as rs769562373, COSV65358414; called by muse, mutect2, varscan2
- PHF3 | c.5687G>A p.R1896H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs993363267, COSV50344815; called by muse, mutect2, varscan2
- PPP2R3A | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV99388482; called by muse, mutect2
- PSORS1C2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV52536157, COSV52536731; called by muse, mutect2, varscan2
- PTPRN | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747918524, COSV55346645; called by muse, mutect2, varscan2
- PTPRZ1 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs760236914, COSV66430887; called by muse, mutect2, varscan2
- RABGAP1L | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs1374812072, COSV52286688; called by muse, mutect2
- ROBO1 | c.3911C>T p.P1304L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs768272871, COSV101458587, COSV71398866; called by muse, mutect2, varscan2
- RTKN | c.1492C>T p.P498S (on ENST00000272430 / NM_001015055.2; = p.P485S on NM_033046.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51962731, COSV51966475; called by muse, mutect2, varscan2
- SCGB3A2 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57023891; called by muse, mutect2, varscan2
- SEL1L2 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs754101601, COSV53158821; called by muse, mutect2, varscan2
- SH3RF3 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.255); catalogued as COSV58696113; called by muse, mutect2
- SLC6A2 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs1345478335, COSV54913121; called by muse, mutect2, varscan2
- SMAD5 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV72505763; called by muse, mutect2, varscan2
- SPTA1 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs373548086; called by muse, mutect2, varscan2
- SRGAP3 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV64540541; called by muse, mutect2, varscan2
- STARD6 | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57143691, COSV57143748; called by muse, mutect2
- STX3 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs151157690; called by muse, mutect2, varscan2
- SWT1 | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV62259344; called by muse, mutect2, varscan2
- TJP1 | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV62046948; called by muse, mutect2, varscan2
- TM2D3 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.073); catalogued as COSV60107507, COSV60109760; called by muse, mutect2, varscan2
- TNIK | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV52690687; called by muse, mutect2, varscan2
- TPMT | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV59430146; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100389983; called by muse, mutect2, varscan2
- TRIM69 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as rs749171075, COSV57805500; called by muse, mutect2, varscan2
- TRPM2 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs550041022, COSV55977723; called by muse, mutect2, varscan2
- UBQLN3 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV100294044; called by muse, mutect2, varscan2
- UBR2 | c.4640G>C p.C1547S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65752856; called by muse, mutect2, varscan2
- UGT2B28 | c.1310+1G>A p.X437_splice | Splice Site (SNP) | VAF 136/277 reads (49%) | catalogued as rs759599479, COSV59431643, COSV59432695; called by muse, mutect2, varscan2
- UNC80 | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV99781103, COSV99781476; called by muse, mutect2, varscan2
- WDR47 | c.2122G>C p.D708H (on ENST00000369962 / NM_001142551.2; = p.D709H on NM_014969.5) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100728497; called by muse, mutect2, varscan2
- ZC3H12C | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs769365245, COSV53713163; called by muse, mutect2, varscan2
- ZGRF1 | c.5773C>T p.Q1925* | Nonsense Mutation (SNP) | VAF 33/61 reads (54%) | catalogued as COSV71393177, COSV71393865; called by muse, mutect2, varscan2
- ZNF521 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64123519; called by muse, mutect2, varscan2
- ZNF835 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV73379401; called by mutect2, varscan2
- ZSWIM4 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV54319191, COSV54319378; called by mutect2, varscan2
- LLGL2 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- PLEKHH3 | c.1160_1161del p.E387Afs*86 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- TPR | c.6051_6052dup p.T2018Kfs*69 | Frame Shift Ins (INS) | VAF 9/99 reads (9%) | called by mutect2, pindel
- USB1 | c.462_465dup p.N156Cfs*20 | Frame Shift Ins (INS) | VAF 53/236 reads (22%) | called by mutect2, pindel, varscan2
- ADAM17 | c.2061C>T p.F687= | Silent (SNP) | VAF 25/207 reads (12%) | catalogued as COSV60402043; called by muse, mutect2, varscan2
- ADAMTS10 | c.699A>G p.R233= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54359909; called by muse, mutect2, varscan2
- ADAMTS13 | c.3681C>T p.L1227= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1554795896, COSV52471908; called by muse, mutect2, varscan2
- ADCK1 | c.105C>T p.G35= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs370327529; called by muse, mutect2, varscan2
- CDH8 | c.993G>A p.Q331= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs775029800, COSV54903268; called by muse, mutect2, varscan2
- CHRM1 | c.327C>T p.S109= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV61007966; called by muse, mutect2, varscan2
- CHST15 | c.1308C>T p.R436= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs749065964, COSV60566111; called by muse, mutect2, varscan2
- EFL1 | c.2817G>A p.E939= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV51610323; called by muse, mutect2, varscan2
- EGR2 | c.963G>A p.L321= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54349079; called by muse, mutect2, varscan2
- HGSNAT | c.801C>T p.F267= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV65535852; called by muse, mutect2, varscan2
- ITIH3 | c.48C>T p.S16= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99835696; called by muse, mutect2, varscan2
- KCTD19 | c.1713C>A p.I571= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV100431317; called by muse, mutect2, varscan2
- KLF7 | c.672C>T p.N224= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as rs201005804, COSV58743383; called by muse, mutect2, varscan2
- KRT77 | c.597G>A p.L199= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1318333920, COSV59241657; called by muse, mutect2, varscan2
- NLGN4Y | c.2427C>T p.H809= | Silent (SNP) | VAF 78/99 reads (79%) | catalogued as rs1317658337, COSV59300307; called by muse, mutect2, varscan2
- NTRK2 | c.1803C>G p.V601= (on ENST00000323115 / NM_001369534.1; = p.V617= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV52884358; called by muse, mutect2, varscan2
- OBSCN | c.16866G>A p.T5622= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs375507173; called by muse, mutect2, varscan2
- PCLO | c.831T>C p.D277= | Silent (SNP) | VAF 26/418 reads (6%) | catalogued as COSV61670255; called by muse, mutect2
- QKI | c.939G>A p.A313= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs765276688, COSV51701071, COSV99275639; called by muse, mutect2, varscan2
- RANBP2 | c.1680C>T p.N560= | Silent (SNP) | VAF 220/716 reads (31%) | catalogued as COSV51709429; called by muse, mutect2, varscan2
- RBM28 | c.2073C>T p.P691= | Silent (SNP) | VAF 55/264 reads (21%) | catalogued as rs770210501, COSV56165037; called by muse, mutect2, varscan2
- REL | c.861C>T p.Y287= | Silent (SNP) | VAF 43/395 reads (11%) | catalogued as rs765395827, COSV99692343, COSV99692497; called by muse, mutect2, varscan2
- SGPP2 | c.750C>T p.P250= | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as rs766037423, COSV58329279, COSV58332111; called by muse, mutect2, varscan2
- SLC5A5 | c.1119T>C p.P373= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV55835809; called by muse, mutect2, varscan2
- SLC7A1 | c.567C>T p.V189= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV66331985; called by muse, mutect2, varscan2
- SPNS1 | c.387C>T p.C129= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs778204826, COSV57953603; called by muse, mutect2, varscan2
- SPX | c.270G>A p.A90= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs547568893, COSV57020748; called by muse, mutect2, varscan2
- TRIM58 | c.753G>C p.V251= | Silent (SNP) | VAF 24/264 reads (9%) | catalogued as COSV63572434; called by muse, mutect2
- UST | c.402C>T p.V134= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV66550712; called by muse, mutect2, varscan2
- WDR59 | c.2784C>T p.H928= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs372404261; called by muse, mutect2, varscan2
- WIPF3 | c.1302G>A p.P434= | Silent (SNP) | VAF 16/177 reads (9%) | catalogued as rs779515341, COSV54209316; called by muse, mutect2, varscan2
- ZNF678 | c.585A>G p.Q195= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs767125578, COSV59388892; called by muse, mutect2, varscan2
- ZZEF1 | c.6774A>G p.G2258= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101068236; called by mutect2, varscan2
- OTUD6B | c.-3G>C | 5'UTR (SNP) | VAF 28/244 reads (11%) | catalogued as COSV53444707; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-45808C>A | Intron (SNP) | VAF 15/212 reads (7%) | catalogued as COSV67450763; called by muse, mutect2
